Somatic mutation profile of tumor specimen TCGA-HT-7877-01A (aliquot TCGA-HT-7877-01A-11D-2395-08) from TCGA case TCGA-HT-7877, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 20.8 years (7,581 days).
Specimen TCGA-HT-7877-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ccf1391-af1c-4cee-87f6-729b2041c87a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7877-10A (Blood Derived Normal), aliquot TCGA-HT-7877-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a21cf7ae-7c95-433e-9b15-e76b97d31a84

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF9 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as rs1135401795, COSV53636533; ClinVar: pathogenic; called by muse, mutect2
- CIC | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 18/101 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157030312, COSV50547633; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- GPR25 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV58498992; called by muse, mutect2
- MAMLD1 | c.1076C>G p.P359R | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV53379552, COSV99476267; called by muse, mutect2, varscan2
- NOL12 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs757854451, COSV63031556; called by muse, mutect2, varscan2
- PLCB2 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1193739585, COSV53031170; called by muse, mutect2, varscan2
- SPTBN5 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.098); catalogued as rs777104635, COSV58026395; called by muse, mutect2, varscan2
- VPS25 | c.201A>G p.R67= | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as COSV53821781; called by muse, varscan2
- NUDT11 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.049); called by muse, mutect2
- SNRNP200 | c.1974_1995del p.E659Vfs*39 | Frame Shift Del (DEL) | VAF 30/160 reads (19%) | called by mutect2, pindel
- AARS2 | c.2202G>A p.L734= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as rs886061486, COSV55117047; ClinVar: uncertain significance; called by muse, mutect2
- ARHGDIB | c.540C>T p.D180= | Silent (SNP) | VAF 66/221 reads (30%) | catalogued as rs776957092, COSV56764300; called by muse, mutect2, varscan2
- FARP1 | c.1872C>T p.G624= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs775560281, COSV60345314; called by muse, mutect2, varscan2
- MYO1A | c.2694C>T p.A898= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as rs748197044, COSV55656765; called by muse, mutect2
- RAB33A | c.6G>A p.A2= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV57063045; called by muse, varscan2
